Gene-level copy-number profile of tumor specimen TARGET-51-PAJNCV-01A from TARGET case TARGET-51-PAJNCV, project TARGET-CCSK (Clear Cell Sarcoma of the Kidney). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.0 years (1,112 days).
Specimen TARGET-51-PAJNCV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-CCSK.04b9ef31-6a8b-5049-abf2-14b352503712.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-51-PAJNCV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/5c702c45-7c5d-4cd6-8119-bcd50872d815

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,388; copy number 1: 327; copy number 2: 57,556; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr2:127,170,011–127,170,231, 1 gene: NIFKP9.
- chr5:72,439,903–72,442,387, 1 gene: AC093278.2.
- chr18:54,879,457–54,880,809, 1 gene: AC007673.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:41,271,311–41,271,835, 1 gene, copy number 11: KRTAP9-11P.

Autosomal genes at a single copy (total copy number 1): 327. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
